Gene-level copy-number profile of tumor specimen REBC-AC9D-TTP1-A from REBC case REBC-AC9D, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-AC9D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 57a9d734-0a92-409c-a294-7d4ffadcab26.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-AC9D-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/278c666a-c857-42c3-ac08-77d5af30a095

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 47; copy number 2: 57,946; copy number 3: 380; copy number 4: 14; copy number 5: 9; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,315,040–2,391,707, 5 genes, copy number 5: AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2.
- chr2:197,569–266,398, 2 genes, copy number 5 (within-gene range 2–5): AC079779.1, SH3YL1.
- chr3:196,739,857–196,832,647, 1 gene, copy number 7 (within-gene range 2–7): PAK2.
- chr3:196,784,980–196,785,086, 1 gene, copy number 7: RNU6-42P.
- chr15:76,993,359–77,045,160, 2 genes, copy number 5: PSTPIP1, AC090181.1.

Autosomal genes at a single copy (total copy number 1): 47. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
